CCDI case PBCGBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Accessory sinuses.
https://portal.gdc.cancer.gov/cases/1dead46a-d22d-4642-87fb-c9caafbf4568

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Accessory sinus, NOS; Age at diagnosis: 19.8 years (7,232 days).

Biospecimens (3 samples)
- Sample 0DRGEI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRGEP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRGEZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
